Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5788, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5788-01A (Primary Tumor).

TCGA-CH-5788

Diagnosis

1. Acinar adenocarcinoma of the prostate (Gleason 4+3 = 7; Gleason 4 and 5: 70%; also Gleason 2 5%) in both lateral lobes with left-sided predominance and extensive perineural infiltration.

Maximum tumor diameter: 30 mm.

Multifocal, in parts extensive extraprostatic bilateral tumor growth at the base and on the seminal vesicles.

Numerous tumor invasions of lymph vessels with a lymph node metastasis in the periprostatic fatty tissue of the prostatectomy preparation.

Minimal safety margin to the (blue labeled) left rectolateral resection margin (3rd disk): 0.2 mm.

Complete tumor resection.

Normal resection margins of bilateral seminal ducts.

2. Tumor-free lipomatous lymph nodes at the right external iliac artery (0/4).
3. Tumor-free lipomatous lymph nodes at the right obturator fossa (0/6).
4. Lymph node metastases at right internal iliac artery with max. size of metastases 0.8 cm (3/4).
5. Tumor-free lipomatous lymph node at the left external iliac artery (0/1).
6. Lymph node metastases of the left obturator fossa with max. size of metastases 3.0 cm (2/4).
7. Tumor-free lipomatous lymph node of the left internal iliac artery (0/1).

Remark

Tumor classification: pT3b, pN1 (6/21), L0, V0. Complete local resection.

Source: NCI Genomic Data Commons file f9caf1a9-b575-4b04-8d86-8a757c68a257 (TCGA-CH-5788.41E797AE-DB60-4653-9E61-4050EC9C05B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).